Gene-level copy-number profile of tumor specimen HCM-SANG-1312-C20-08A-01D-A80T-32 from HCMI case HCM-SANG-1312-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-1312-C20-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0328baee-bb2f-4c75-b3a2-96d7bff8807c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1312-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/1a20a464-1b97-4bc0-a1b0-0038c97381b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 3,055; copy number 2: 55,851; copy number 5: 1; copy number 6: 5; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,227,718–10,227,803, 1 gene (within-gene range 0–2): AL358013.1.
- chr18:1,176,790–1,177,012, 1 gene: COX6CP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,269,704–38,382,272, 1 gene, copy number 6 (within-gene range 2–6): NSD3.
- chr8:38,335,981–38,560,939, 8 genes, copy number 5–8 (within-gene range 2–8): AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86.

Autosomal genes at a single copy (total copy number 1): 199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
